Somatic mutation profile of tumor specimen 47b9deba-dea0-4e0c-8b0a-4864c3 (aliquot 47b9deba-dea0-4e0c-8b0a-4864c3_D6) from CPTAC case 16CO003, project CPTAC-2 (Colon — Adenomas and Adenocarcinomas). Sex at birth: female; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIA.
Specimen 47b9deba-dea0-4e0c-8b0a-4864c3: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) adcf2f34-5d20-49bf-942a-e444a350ae0f.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen b078ea81-4c88-4864-9de5-7c25a3 (Blood Derived Normal), aliquot b078ea81-4c88-4864-9de5-7c25a3_D1_1; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/950045b2-a778-408c-94b7-a6761824091f

The open-access MAF lists 167 somatic variants for this specimen: 105 protein-altering or splice-affecting, 44 silent, 18 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 91, Silent 44, Intron 11, Nonsense Mutation 4, Splice Site 4, 5'UTR 3, Frame Shift Ins 2, RNA 2, Frame Shift Del 2, Splice Region 2, 3'Flank 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.1024C>T p.R342* | Nonsense Mutation (SNP) | VAF 66/159 reads (42%) | hotspot (GDC flag); catalogued as rs730882029, CM004908, COSV52665487; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADCY9 | c.3523G>A p.G1175R | Missense Mutation (SNP) | VAF 59/314 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1158584676; called by muse, mutect2, varscan2
- ADGRA3 | c.3194G>A p.R1065Q | Missense Mutation (SNP) | VAF 46/218 reads (21%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.565); catalogued as rs144467569; called by muse, mutect2, varscan2
- AHNAK | c.15725G>A p.G5242D | Missense Mutation (SNP) | VAF 35/228 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV99949301; called by muse, mutect2, varscan2
- ANKRD13B | c.1258+1G>A p.X420_splice | Splice Site (SNP) | VAF 43/170 reads (25%) | catalogued as COSV61470601; called by muse, mutect2, varscan2
- CCR2 | c.956C>T p.A319V | Missense Mutation (SNP) | VAF 23/112 reads (21%) | SIFT tolerated (0.35); PolyPhen benign (0.018); catalogued as rs747406014; called by muse, mutect2, varscan2
- CLTCL1 | c.922C>G p.P308A | Missense Mutation (SNP) | VAF 15/137 reads (11%) | SIFT tolerated (0.28); PolyPhen benign (0.2); catalogued as COSV54230917; called by muse, mutect2, varscan2
- COL5A3 | c.187C>T p.R63W | Missense Mutation (SNP) | VAF 59/152 reads (39%) | SIFT tolerated (0.12); PolyPhen benign (0.249); catalogued as rs769312436; called by muse, mutect2, varscan2
- CRP | c.617G>A p.R206Q | Missense Mutation (SNP) | VAF 18/186 reads (10%) | SIFT tolerated (0.77); PolyPhen benign (0.024); catalogued as rs774544095, COSV54814703, COSV54814922; called by muse, mutect2
- CSMD1 | c.6868G>A p.G2290R (on ENST00000520002; = p.G2289R on NM_033225.6) | Missense Mutation (SNP) | VAF 17/70 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1450938941; called by muse, mutect2, varscan2
- FAM124A | c.742G>A p.E248K (on ENST00000322475 / NM_001242312.2; = p.E284K on NM_145019.4) | Missense Mutation (SNP) | VAF 30/512 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.031); catalogued as rs774168466, COSV99696305; called by muse, mutect2
- GABRA6 | c.518A>C p.K173T | Missense Mutation (SNP) | VAF 12/286 reads (4%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.991); catalogued as rs1270279109, COSV50877438, COSV99194040; called by muse, mutect2
- GAS2L2 | c.2035G>T p.G679C | Missense Mutation (SNP) | VAF 27/131 reads (21%) | SIFT tolerated (0.08); PolyPhen benign (0.019); catalogued as rs971733270; called by muse, mutect2, varscan2
- GLI2 | c.2995G>A p.D999N (on ENST00000361492 / NM_001374353.1; = p.D1016N on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 34/128 reads (27%) | SIFT tolerated (0.07); PolyPhen benign (0.199); catalogued as rs1365347989; called by muse, varscan2
- IGFALS | c.1399C>T p.R467C | Missense Mutation (SNP) | VAF 249/783 reads (32%) | SIFT tolerated (0.09); PolyPhen possibly damaging (0.684); catalogued as rs373710655, COSV99236606; called by muse, mutect2, varscan2
- KCNH5 | c.2651C>T p.P884L | Missense Mutation (SNP) | VAF 38/198 reads (19%) | SIFT deleterious, low confidence (0.03); PolyPhen benign (0.229); catalogued as rs144667189, COSV59781173; called by muse, varscan2
- KCNS3 | c.431C>G p.S144C | Missense Mutation (SNP) | VAF 22/262 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.334); catalogued as rs201851493; called by muse, mutect2
- KMT2D | c.10957G>A p.G3653R | Missense Mutation (SNP) | VAF 16/74 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.106); catalogued as rs780464972, COSV56456565, COSV99977466; called by muse, mutect2, varscan2
- MAGEB16 | c.390G>A p.M130I | Missense Mutation (SNP) | VAF 52/291 reads (18%) | SIFT tolerated (0.13); PolyPhen benign (0.036); catalogued as COSV67873931; called by muse, mutect2
- MAPK7 | c.976C>T p.R326C | Missense Mutation (SNP) | VAF 93/432 reads (22%) | SIFT deleterious (0.02); PolyPhen benign (0.003); catalogued as rs761235886, COSV55191632; called by muse, mutect2, varscan2
- MOBP | c.215G>A p.R72H (on ENST00000420739; = p.R96H on NM_001278322.2) | Missense Mutation (SNP) | VAF 40/160 reads (25%) | PolyPhen probably damaging (0.991); catalogued as rs763986350; called by muse, varscan2
- OR10R2 | c.520T>G p.L174V | Missense Mutation (SNP) | VAF 25/331 reads (8%) | SIFT tolerated (0.22); PolyPhen benign (0.12); catalogued as COSV63768399, COSV63769239; called by muse, mutect2
- OR5D18 | c.427G>A p.V143M | Missense Mutation (SNP) | VAF 40/424 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.009); catalogued as rs577643505, COSV61738236, COSV61738342; called by muse, mutect2
- PCDHA4 | c.64G>A p.A22T | Missense Mutation (SNP) | VAF 36/156 reads (23%) | SIFT tolerated, low confidence (0.43); PolyPhen benign (0.007); catalogued as rs782583105, COSV63544869; called by muse, mutect2, varscan2
- PDZD4 | c.1481G>A p.R494Q | Missense Mutation (SNP) | VAF 12/200 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.644); catalogued as rs1260319617, COSV51245914; called by muse, mutect2
- PHLDB3 | c.940G>A p.A314T | Missense Mutation (SNP) | VAF 22/184 reads (12%) | SIFT tolerated (0.19); PolyPhen probably damaging (0.994); catalogued as rs752680293; called by muse, mutect2, varscan2
- POLR2B | c.101T>G p.F34C | Missense Mutation (SNP) | VAF 5/30 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58900241; called by muse, mutect2, varscan2
- PREX1 | c.1436-2A>G p.X479_splice | Splice Site (SNP) | VAF 10/190 reads (5%) | catalogued as COSV100906359; called by muse, mutect2
- PRKAA2 | c.1655G>A p.R552H | Missense Mutation (SNP) | VAF 25/126 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.84); catalogued as rs1387624099; called by muse, varscan2
- PTPRC | c.3361C>G p.Q1121E | Missense Mutation (SNP) | VAF 20/248 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV100723371; called by muse, mutect2
- PYGM | c.2203C>T p.R735C | Missense Mutation (SNP) | VAF 81/486 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.771); catalogued as rs559363120; called by muse, mutect2, varscan2
- RHBDF1 | c.334C>T p.R112C | Missense Mutation (SNP) | VAF 92/394 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as rs754407394, COSV51958459; called by mutect2, varscan2
- RNF20 | c.2444A>G p.N815S | Missense Mutation (SNP) | VAF 12/76 reads (16%) | SIFT tolerated (0.92); PolyPhen benign (0.035); catalogued as COSV66661622; called by mutect2, varscan2
- SCN2A | c.2057G>C p.S686T | Missense Mutation (SNP) | VAF 27/223 reads (12%) | SIFT tolerated (0.23); PolyPhen probably damaging (0.911); catalogued as COSV51847902; called by muse, mutect2, varscan2
- SGCG | c.344C>T p.A115V | Missense Mutation (SNP) | VAF 42/142 reads (30%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.984); catalogued as rs774245371, COSV104374639, COSV54565704; called by muse, mutect2
- SH3RF3 | c.664G>A p.V222I | Missense Mutation (SNP) | VAF 54/556 reads (10%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs565113287; called by muse, mutect2
- SVIL | c.5672C>A p.P1891H (on ENST00000355867 / NM_021738.3; = p.P1465H on NM_003174.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 117/702 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.76); catalogued as COSV63446333; called by muse, mutect2, varscan2
- TGS1 | c.961A>G p.I321V | Missense Mutation (SNP) | VAF 27/140 reads (19%) | SIFT deleterious (0.02); PolyPhen benign (0.416); catalogued as rs1324367254; called by muse, mutect2, varscan2
- TRIM64 | c.1215A>C p.Q405H | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.489); catalogued as COSV59839961; called by muse, mutect2, varscan2
- TRPA1 | c.1829A>C p.K610T | Missense Mutation (SNP) | VAF 24/165 reads (15%) | SIFT tolerated (0.6); PolyPhen benign (0); catalogued as COSV51576229; called by muse, mutect2, varscan2
- WASF3 | c.814G>A p.V272M | Missense Mutation (SNP) | VAF 80/280 reads (29%) | SIFT tolerated (0.16); PolyPhen benign (0.006); catalogued as rs762342891, COSV58971791; called by muse, mutect2, varscan2
- WWP1 | c.67A>C p.T23P | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.864); catalogued as COSV99617164; called by muse, mutect2, varscan2
- ZNF208 | c.2639A>G p.K880R | Missense Mutation (SNP) | VAF 24/198 reads (12%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.942); catalogued as COSV68106519; called by muse, mutect2, varscan2
- ACSL4 | c.879C>A p.S293R (on ENST00000340800 / NM_022977.2; = p.S252R on NM_004458.3 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 28/349 reads (8%) | SIFT tolerated (0.32); PolyPhen benign (0.101); called by muse, mutect2
- ADGRG3 | c.318C>A p.D106E | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.551); called by muse, mutect2, varscan2
- ADGRV1 | c.3526G>T p.V1176F | Missense Mutation (SNP) | VAF 3/40 reads (8%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.901); called by muse, mutect2
- APPBP2 | c.1529del p.Y510Sfs*4 | Frame Shift Del (DEL) | VAF 6/44 reads (14%) | called by mutect2, pindel, varscan2
- ARHGEF17 | c.6055C>T p.P2019S | Missense Mutation (SNP) | VAF 66/318 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- ARID1B | c.5767C>T p.H1923Y | Missense Mutation (SNP) | VAF 64/283 reads (23%) | SIFT deleterious (0.01); PolyPhen benign (0.091); called by muse, mutect2, varscan2
- ASPN | c.825C>A p.N275K | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by mutect2, varscan2
- CD34 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 61/247 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- CELF2 | c.1415A>G p.D472G (on ENST00000416382 / NM_001025077.3; = p.D485G on NM_006561.3 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 16/81 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); called by muse, mutect2
- CFHR1 | c.551G>C p.G184A | Missense Mutation (SNP) | VAF 16/140 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- CRB1 | c.2393T>G p.L798W | Missense Mutation (SNP) | VAF 17/350 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- CYB561 | c.563+1G>C p.X188_splice | Splice Site (SNP) | VAF 18/163 reads (11%) | called by muse, mutect2, varscan2
- DCAF1 | c.2888_2889dup p.P964Gfs*28 | Frame Shift Ins (INS) | VAF 33/248 reads (13%) | called by mutect2, pindel, varscan2
- DMRTA2 | c.290C>G p.A97G | Missense Mutation (SNP) | VAF 40/154 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.952); called by muse, mutect2, varscan2
- DNAH14 | c.1063G>T p.E355* (on ENST00000445597; = p.E336* on NM_001145154.3) | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | called by muse, mutect2, varscan2
- FAM71B | c.478A>C p.T160P | Missense Mutation (SNP) | VAF 11/264 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.828); called by muse, mutect2
- FASN | c.5758A>G p.I1920V | Missense Mutation (SNP) | VAF 72/832 reads (9%) | SIFT tolerated (0.37); PolyPhen benign (0.022); called by muse, mutect2
- FAT3 | c.3305C>T p.A1102V | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.068); called by muse, mutect2
- FCGR2B | c.919C>T p.Q307* | Nonsense Mutation (SNP) | VAF 6/84 reads (7%) | called by muse, mutect2
- GABARAPL2 | c.263+4A>C | Splice Region (SNP) | VAF 7/34 reads (21%) | called by muse, mutect2, varscan2
- GID4 | c.754G>A p.A252T | Missense Mutation (SNP) | VAF 18/204 reads (9%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); called by muse, mutect2
- HECW1 | c.595C>A p.Q199K | Missense Mutation (SNP) | VAF 11/136 reads (8%) | SIFT tolerated (0.06); PolyPhen benign (0.139); called by muse, mutect2
- KLHL4 | c.1926G>C p.R642= | Splice Region (SNP) | VAF 10/105 reads (10%) | called by muse, mutect2, varscan2
- LMO7 | c.4680G>T p.K1560N (on ENST00000357063; = p.K1241N on NM_005358.5) | Missense Mutation (SNP) | VAF 19/159 reads (12%) | SIFT deleterious (0.02); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- MAB21L3 | c.960_961insA p.Q321Tfs*22 | Frame Shift Ins (INS) | VAF 44/278 reads (16%) | called by mutect2, pindel, varscan2
- MARCO | c.486G>A p.M162I | Missense Mutation (SNP) | VAF 24/239 reads (10%) | SIFT tolerated (0.26); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- MYO15A | c.2252G>C p.R751T | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.031); called by muse, mutect2
- NCOA6 | c.2308C>G p.Q770E | Missense Mutation (SNP) | VAF 58/431 reads (13%) | SIFT deleterious (0); PolyPhen benign (0.237); called by muse, mutect2, varscan2
- NDUFAF1 | c.690C>A p.F230L | Missense Mutation (SNP) | VAF 67/202 reads (33%) | SIFT tolerated (0.57); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- OR2AJ1 | c.509G>C p.G170A | Missense Mutation (SNP) | VAF 47/307 reads (15%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.525); called by muse, mutect2, varscan2
- OR8K3 | c.932T>A p.F311Y | Missense Mutation (SNP) | VAF 16/87 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.049); called by muse, mutect2, varscan2
- PCDHA11 | c.625A>C p.N209H | Missense Mutation (SNP) | VAF 20/101 reads (20%) | SIFT tolerated, low confidence (1); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PDCD6IP | c.2231C>T p.P744L | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- PREX2 | c.136G>T p.V46L | Missense Mutation (SNP) | VAF 58/290 reads (20%) | SIFT tolerated (0.65); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- PREX2 | c.4335C>G p.N1445K | Missense Mutation (SNP) | VAF 4/66 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.045); called by muse, mutect2
- PRICKLE3 | c.147C>A p.C49* | Nonsense Mutation (SNP) | VAF 16/373 reads (4%) | called by muse, mutect2
- PRSS12 | c.1916+2T>G p.X639_splice | Splice Site (SNP) | VAF 16/124 reads (13%) | called by muse, mutect2, varscan2
- PRSS35 | c.28T>G p.F10V | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT deleterious (0.03); PolyPhen benign (0.003); called by muse, mutect2, varscan2
- PSD | c.974C>T p.P325L | Missense Mutation (SNP) | VAF 40/151 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0); called by muse, mutect2, varscan2
- PTGES2 | c.598A>C p.K200Q | Missense Mutation (SNP) | VAF 27/256 reads (11%) | SIFT deleterious (0.03); PolyPhen benign (0.347); called by muse, mutect2, varscan2
- RBMS3 | c.743A>T p.E248V | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.141); called by muse, mutect2
- SATB2 | c.2027T>C p.L676P | Missense Mutation (SNP) | VAF 108/505 reads (21%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.796); called by muse, mutect2, varscan2
- SLC17A5 | c.1103G>T p.S368I | Missense Mutation (SNP) | VAF 23/172 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.446); called by muse, mutect2, varscan2
- SLC25A23 | c.944A>G p.Y315C | Missense Mutation (SNP) | VAF 25/158 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- SLCO4C1 | c.1335A>T p.K445N | Missense Mutation (SNP) | VAF 6/68 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); called by muse, mutect2
- SNTA1 | c.925A>G p.T309A | Missense Mutation (SNP) | VAF 18/400 reads (5%) | SIFT tolerated (0.84); PolyPhen benign (0); called by muse, mutect2
- SNX30 | c.433G>A p.E145K | Missense Mutation (SNP) | VAF 24/111 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.173); called by muse, mutect2, varscan2
- SOHLH2 | c.463C>G p.L155V | Missense Mutation (SNP) | VAF 11/87 reads (13%) | SIFT tolerated (0.52); PolyPhen benign (0.006); called by muse, mutect2, varscan2
- SPEN | c.3742T>A p.S1248T | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- SPTB | c.5080C>A p.Q1694K | Missense Mutation (SNP) | VAF 50/445 reads (11%) | SIFT tolerated (0.18); PolyPhen benign (0.227); called by muse, mutect2, varscan2
- THAP9 | c.1854G>A p.M618I | Missense Mutation (SNP) | VAF 6/112 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.001); called by muse, mutect2
- TLR7 | c.1788G>T p.K596N | Missense Mutation (SNP) | VAF 11/84 reads (13%) | SIFT tolerated (0.4); PolyPhen benign (0.001); called by muse, mutect2, varscan2
- TMEM144 | c.938T>A p.M313K | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- TMEM179 | c.79C>T p.P27S | Missense Mutation (SNP) | VAF 8/35 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2, varscan2
- TMPRSS15 | c.1909T>A p.L637M | Missense Mutation (SNP) | VAF 30/446 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, mutect2
- TRIM22 | c.446A>G p.Q149R | Missense Mutation (SNP) | VAF 9/58 reads (16%) | SIFT tolerated (0.19); PolyPhen benign (0); called by muse, mutect2, varscan2
- ZFPM1 | c.1972G>A p.A658T | Missense Mutation (SNP) | VAF 17/41 reads (41%) | SIFT tolerated (0.16); PolyPhen benign (0.013); called by muse, mutect2, varscan2
- ZNF433 | c.1154A>G p.E385G | Missense Mutation (SNP) | VAF 10/78 reads (13%) | SIFT deleterious (0.03); PolyPhen benign (0.085); called by muse, mutect2, varscan2
- ZNF672 | c.656A>T p.Q219L | Missense Mutation (SNP) | VAF 14/372 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.171); called by muse, mutect2
- ZNF682 | c.215C>A p.A72D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT tolerated (0.26); PolyPhen benign (0.005); called by muse, mutect2, varscan2
- ZNF710 | c.1550G>A p.R517Q | Missense Mutation (SNP) | VAF 68/211 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); called by muse, mutect2, varscan2
- ZNF768 | c.1570del p.Q524Rfs*37 | Frame Shift Del (DEL) | VAF 26/189 reads (14%) | called by mutect2, pindel, varscan2
- ABCD1 | c.2158C>T p.L720= | Silent (SNP) | VAF 27/309 reads (9%) | called by muse, mutect2
- ACVR2B | c.1503C>T p.T501= | Silent (SNP) | VAF 20/260 reads (8%) | called by muse, mutect2
- ADAMTS19 | c.2727T>C p.P909= | Silent (SNP) | VAF 20/137 reads (15%) | called by muse, mutect2, varscan2
- ADGRL3 | c.489C>T p.T163= (on ENST00000506720 / NM_001322402.2; = p.T95= on NM_015236.6) | Silent (SNP) | VAF 14/80 reads (18%) | catalogued as COSV72269894; called by muse, mutect2, varscan2
- ANK1 | c.4683G>A p.L1561= | Silent (SNP) | VAF 27/143 reads (19%) | called by muse, mutect2, varscan2
- ANKFN1 | c.3414C>T p.S1138= (on ENST00000653862; = p.S991= on NM_001365758.1 and 1 other RefSeq transcript) | Silent (SNP) | VAF 24/392 reads (6%) | catalogued as rs1041991870; called by muse, mutect2
- APOBR | c.2319G>A p.L773= (on ENST00000431282; = p.L782= on NM_018690.4) | Silent (SNP) | VAF 10/124 reads (8%) | called by muse, mutect2
- ARGLU1 | c.267G>A p.V89= | Silent (SNP) | VAF 22/239 reads (9%) | catalogued as COSV62271598; called by muse, mutect2
- ARID1A | c.774C>T p.S258= | Silent (SNP) | VAF 14/38 reads (37%) | catalogued as rs1433223379; called by muse, mutect2, varscan2
- ARL4D | c.381C>T p.G127= | Silent (SNP) | VAF 231/562 reads (41%) | catalogued as rs941492394, COSV60721436; called by muse, mutect2, varscan2
- BICD2 | c.1341C>T p.G447= | Silent (SNP) | VAF 52/413 reads (13%) | catalogued as rs750241183, COSV63551129; called by muse, mutect2, varscan2
- C16orf96 | c.1296A>C p.S432= | Silent (SNP) | VAF 17/175 reads (10%) | called by mutect2, varscan2
- CHRNA1 | c.258C>G p.R86= | Silent (SNP) | VAF 19/203 reads (9%) | called by muse, mutect2, varscan2
- COL5A2 | c.3912C>T p.S1304= | Silent (SNP) | VAF 14/258 reads (5%) | catalogued as rs571598585; called by muse, mutect2
- CUX2 | c.1623C>T p.G541= | Silent (SNP) | VAF 37/184 reads (20%) | catalogued as rs750439909, COSV55624883; called by muse, mutect2, varscan2
- FAM50A | c.795C>T p.Y265= | Silent (SNP) | VAF 72/794 reads (9%) | catalogued as rs367764750, COSV99340980; called by muse, mutect2
- FRMD3 | c.1527G>A p.S509= | Silent (SNP) | VAF 20/271 reads (7%) | catalogued as rs556942996; called by muse, mutect2
- GALNT9 | c.1032C>T p.P344= | Silent (SNP) | VAF 66/361 reads (18%) | catalogued as rs1381487011; called by muse, mutect2, varscan2
- GJA9 | c.1032A>G p.Q344= | Silent (SNP) | VAF 30/142 reads (21%) | called by muse, mutect2, varscan2
- IL1RAPL2 | c.1950C>T p.N650= | Silent (SNP) | VAF 76/245 reads (31%) | catalogued as rs750449116, COSV61186005; called by muse, mutect2, varscan2
- KCTD19 | c.936C>T p.D312= | Silent (SNP) | VAF 47/177 reads (27%) | catalogued as rs201143823; called by muse, mutect2, varscan2
- LRP5 | c.1563C>T p.D521= | Silent (SNP) | VAF 59/274 reads (22%) | catalogued as rs750457614, COSV53726421; called by muse, mutect2, varscan2
- LRRN3 | c.813T>G p.P271= | Silent (SNP) | VAF 10/125 reads (8%) | called by muse, mutect2
- MYPOP | c.693G>A p.P231= | Silent (SNP) | VAF 29/118 reads (25%) | catalogued as rs1451825698; called by muse, mutect2, varscan2
- NAA15 | c.2028T>G p.L676= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99649825; called by muse, mutect2, varscan2
- NMBR | c.477G>A p.R159= | Silent (SNP) | VAF 26/174 reads (15%) | called by muse, mutect2, varscan2
- OR5AS1 | c.318T>C p.S106= | Silent (SNP) | VAF 18/255 reads (7%) | called by muse, mutect2
- PCDHGA10 | c.1053G>A p.L351= | Silent (SNP) | VAF 16/135 reads (12%) | called by muse, mutect2, varscan2
- PDGFRA | c.411A>G p.L137= | Silent (SNP) | VAF 24/208 reads (12%) | catalogued as rs778364880; called by muse, mutect2
- PINK1 | c.1077G>A p.A359= | Silent (SNP) | VAF 41/255 reads (16%) | catalogued as rs144550985, COSV58631663; ClinVar: likely benign; called by muse, mutect2, varscan2
- PPP1R3F | c.2139A>G p.E713= | Silent (SNP) | VAF 16/274 reads (6%) | called by muse, mutect2
- PRKD3 | c.2259C>T p.Y753= | Silent (SNP) | VAF 12/209 reads (6%) | called by muse, mutect2
- PSMD11 | c.18G>A p.V6= | Silent (SNP) | VAF 22/99 reads (22%) | called by muse, mutect2, varscan2
- PTPRD | c.1923T>C p.I641= | Silent (SNP) | VAF 28/281 reads (10%) | catalogued as rs774207545; called by muse, mutect2, varscan2
- RALY | c.51G>A p.K17= | Silent (SNP) | VAF 85/274 reads (31%) | called by muse, mutect2, varscan2
- RFX7 | c.2860A>C p.R954= (on ENST00000559447 / NM_001368074.1; = p.R1051= on NM_022841.7 and 1 other RefSeq transcript) | Silent (SNP) | VAF 96/424 reads (23%) | called by muse, mutect2, varscan2
- RIMS2 | c.1269T>C p.S423= (on ENST00000666250 / NM_001348490.2; = p.S231= on NM_014677.5 and 7 other RefSeq transcripts) | Silent (SNP) | VAF 19/256 reads (7%) | catalogued as rs778061023, COSV51651026, COSV51655287, COSV51702036; called by muse, mutect2
- SCRIB | c.720C>G p.G240= | Silent (SNP) | VAF 39/470 reads (8%) | catalogued as COSV100252600; called by muse, mutect2
- SLC2A14 | c.300C>T p.I100= | Silent (SNP) | VAF 24/106 reads (23%) | catalogued as rs1480782639; called by muse, mutect2, varscan2
- SLITRK1 | c.672A>G p.K224= | Silent (SNP) | VAF 20/518 reads (4%) | catalogued as rs1208965366, COSV65674934; called by muse, mutect2
- SPRR3 | c.351C>A p.V117= | Silent (SNP) | VAF 129/560 reads (23%) | called by mutect2, varscan2
- TBPL1 | c.534G>A p.V178= | Silent (SNP) | VAF 8/36 reads (22%) | called by muse, mutect2, varscan2
- VEGFD | c.414C>T p.N138= | Silent (SNP) | VAF 68/203 reads (33%) | catalogued as rs757675651, COSV52910897; called by muse, mutect2, varscan2
- VIM | c.396G>A p.L132= | Silent (SNP) | VAF 46/265 reads (17%) | catalogued as rs11545554; called by muse, mutect2, varscan2
- AC098591.2 | n.804T>G | RNA (SNP) | VAF 24/380 reads (6%) | called by muse, mutect2
- BHMT | c.-14T>A | 5'UTR (SNP) | VAF 21/101 reads (21%) | called by muse, mutect2, varscan2
- GRIN1 | c.571-806C>T | Intron (SNP) | VAF 12/74 reads (16%) | catalogued as rs1414926446; called by muse, varscan2
- KIAA1328 | c.1232+16623G>T | Intron (SNP) | VAF 5/22 reads (23%) | called by muse, mutect2
- LINC02054 | n.2388G>A | RNA (SNP) | VAF 71/314 reads (23%) | called by muse, mutect2, varscan2
- MAP2K3 | c.49+6542G>T | Intron (SNP) | VAF 72/451 reads (16%) | called by muse, mutect2, varscan2
- MARCHF1 | c.242+533A>G | Intron (SNP) | VAF 10/110 reads (9%) | catalogued as COSV56832973; called by muse, mutect2
- MARCHF1 | c.-322-86005G>A | Intron (SNP) | VAF 46/234 reads (20%) | catalogued as rs1031772747, COSV72277762; called by muse, mutect2, varscan2
- MPDU1 | c.*366G>A | 3'UTR (SNP) | VAF 33/262 reads (13%) | called by muse, mutect2, varscan2
- PAFAH1B2 | chr11:117171725 C>G | 3'Flank (SNP) | VAF 7/166 reads (4%) | called by muse, mutect2
- PCM1 | c.783+258G>A | Intron (SNP) | VAF 9/70 reads (13%) | catalogued as rs780988654, COSV100279676; called by muse, mutect2, varscan2
- PCTP | c.-29C>G | 5'UTR (SNP) | VAF 11/88 reads (13%) | called by muse, mutect2, varscan2
- PDHA1 | c.832-39C>T | Intron (SNP) | VAF 17/190 reads (9%) | catalogued as rs746759223; called by muse, mutect2
- PSTPIP1 | c.838+140T>G | Intron (SNP) | VAF 12/44 reads (27%) | called by muse, mutect2, varscan2
- RNASEH2B | c.-104dup | 5'UTR (INS) | VAF 4/47 reads (9%) | called by mutect2, pindel
- SEC14L2 | c.424-55C>T | Intron (SNP) | VAF 78/323 reads (24%) | catalogued as rs530575908; called by muse, mutect2, varscan2
- TRO | c.1701-14T>C | Intron (SNP) | VAF 12/152 reads (8%) | called by muse, mutect2
- TTN | c.10361-3969T>G | Intron (SNP) | VAF 19/213 reads (9%) | called by muse, mutect2
